Somatic mutation profile of tumor specimen BA2646D (aliquot aq-BA2646D) from BEATAML1.0 case 2535, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.6 years (22,864 days).
Specimen BA2646D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81fb64f6-4441-4c23-9c9a-f3a98795e285.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2716D (Solid Tissue Normal), aliquot aq-BA2716D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e17afe8-c97b-4e1c-a989-437a4cfda789

The open-access MAF lists 10 somatic variants for this specimen: 2 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 2, Intron 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF467 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1204360327; called by muse, mutect2, varscan2
- CKAP4 | c.1298G>T p.S433I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2
- CEL | c.1785C>G p.P595= (on ENST00000673714; = p.P592= on NM_001807.6) | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs576967034, CD060114, COSV60826310, COSV60828911; called by muse, mutect2, varscan2
- PACSIN1 | c.336G>A p.K112= | Silent (SNP) | VAF 190/403 reads (47%) | called by muse, mutect2, varscan2
- TET1 | c.2811A>C p.V937= | Silent (SNP) | VAF 95/191 reads (50%) | called by muse, mutect2, varscan2
- TMCC1 | c.304C>T p.L102= | Silent (SNP) | VAF 68/152 reads (45%) | called by muse, mutect2, varscan2
- VEZF1 | c.870C>T p.N290= | Silent (SNP) | VAF 122/278 reads (44%) | catalogued as rs1461165975; called by muse, mutect2, varscan2
- CHIT1 | c.*421_*422insTGTT | 3'UTR (INS) | VAF 72/172 reads (42%) | called by mutect2, varscan2
- NUGGC | c.-11C>T | 5'UTR (SNP) | VAF 59/238 reads (25%) | catalogued as rs780325957; called by muse, mutect2, varscan2
- WNT4 | c.313+2210G>A | Intron (SNP) | VAF 127/289 reads (44%) | called by muse, mutect2, varscan2
